TCGA case TCGA-QQ-A8VB — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c323272-2e94-4910-a894-7836570852cd

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (3)
1. Malignant peripheral nerve sheath tumor (the primary disease): ICD-O-3 morphology code: 9540/3; ICD-10 code: C49.6; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of trunk, NOS; Classification of tumor: primary; Age at diagnosis: 68.2 years (24,916 days); Year of diagnosis: 1998; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 3.5; Tumor width measurement: 3.
   Pathology details: Measurement type: Pathologic; Tumor burden: 3.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No.
2. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; Tissue or organ of origin: Skin of trunk; Classification of tumor: Prior primary; Age at diagnosis: 68.2 years (24,916 days).
3. Subsequent primary of the gastrointestinal tract (histology not recorded by GDC). Age at diagnosis: 75.6 years (27,598 days); Days to diagnosis: 2,682 days (7.3 years); Prior treatment: Yes.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 9; Tumor width measurement: 5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 9.

Follow-up (2 entries)
- Days to follow up: 5,324 days (14.6 years); Disease response: Tumor Free.
- Days to follow up: 5,723 days (15.7 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A8VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-QQ-A8VB-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A8VB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A8VB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: NF1; Mpnst plexiform neurofibroma site: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Superficial Trunk - Buttock.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 3; Lesion pathologic depth: 3.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: gastrointestinal; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- New tumor event, New tumor event tumor sizes, New tumor event tumor size: New tumor event lesion pathologic length: 9; New tumor event lesion pathologic width: 5; New tumor event lesion pathologic depth: 4.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Trunk, Superficial; Other malignancy histological type: Mpnst.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 3.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: TSS confirmed this case is a recurrence and not a primary tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,723 days; disease-specific survival: no event (censored), 5,723 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,682 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A8VB-01A-11D-A37B-01): tumor purity 0.91, ploidy 2.69, whole-genome doublings 1.
